Gene-level copy-number profile of tumor specimen TCGA-91-6840-01A from TCGA case TCGA-91-6840, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 59.8 years (21,854 days).
Specimen TCGA-91-6840-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.e522b2b3-eabb-4e4e-b8a6-cee2f3dae0ee.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-91-6840-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/53fd023a-912b-4501-999a-5ac4a2f4a655

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 2,523; copy number 2: 23,039; copy number 3: 16,135; copy number 4: 8,823; copy number 5: 3,702; copy number 6: 4,971; copy number 7: 284; copy number 8: 158; copy number 9: 40; copy number 10: 29; copy number 13: 98.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-91-6840-01A-11D-1943-01): tumor purity 0.62, ploidy 2.84, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:34,228,439–34,346,731, 1 gene (within-gene range 0–1): AC090993.1.
- chr8:34,322,992–35,093,509, 4 genes: RPL10AP3, LINC01288, AC087343.1, AC099685.1.
- chr18:46,667,821–46,802,449, 4 genes: ST8SIA5, AC090311.1, AC090241.2, AC090241.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,282 genes in 45 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:62,957,326–65,432,637, 59 genes, copy number 5 (within-gene range 2–5): AC007098.1, OTX1, AC009501.1, AC009501.2, RPL27P5, DBIL5P2, WDPCP, Metazoa_SRP, MTFR2P1, AC016734.1, MDH1, PRELID1P6, RPS4XP5, RPL27P6, CSP1, HNRNPA1P66, UGP2, AC114748.1, VPS54, AC012368.2, PELI1, AC012368.1, LINC00309, AC012368.3, AC114752.1, AC114752.2, MIR4433B, MIR4433A, RPL23AP37, LGALSL-DT, AC008074.1, LGALSL, LINC01805, AC008074.2, AFTPH, MIR4434, RNU6-100P, LINC02579, SERTAD2, AC007365.1, RPS10P9, RN7SL341P, Y_RNA, AC007880.1, LINC01800, LINC02245, RN7SL211P, RPL11P1, SLC1A4, RNU6-548P, LINC02576, CEP68, RAB1A, SNORA74, AC007318.1, VDAC2P5, ACTR2, SPRED2, AC012370.1.
- chr3:93,843,764–113,812,056, 276 genes, copy number 5–6 (broad region; genes not listed).
- chr3:152,648,146–198,222,513, 799 genes, copy number 5–6 (broad region; genes not listed).
- chr4:13,977,166–15,738,313, 23 genes, copy number 5 (within-gene range 2–5): AC095052.1, LINC01085, AC073848.1, AC092546.1, AC006296.3, AC006296.2, AC006296.1, LINC00504, MTND2P31, SNORA63, CPEB2-DT, CPEB2, C1QTNF7-AS1, RN7SKP170, C1QTNF7, AC099550.1, CC2D2A, AC007016.1, AC116651.1, FBXL5, FAM200B, AC114744.2, BST1.
- chr4:127,880,893–129,116,640, 18 genes, copy number 5: PLK4, RNU6-583P, MFSD8, ABHD18, LARP1B, AC099340.1, FOSL1P1, PGRMC2, LINC02615, AC110609.1, AC078850.1, AC078850.2, JADRR, JADE1, SCLT1, AC093783.1, AC093826.1, C4orf33.
- chr4:134,932,889–135,913,680, 11 genes, copy number 5: AC104619.2, AC104619.4, AC104619.1, AC104619.3, AC107463.1, LINC02485, U6, KRT18P54, TARS2P1, AC105362.1, LINC00613.
- chr5:32,522,758–45,895,970, 219 genes, copy number 5 (broad region; genes not listed).
- chr6:29,301,701–50,021,994, 753 genes, copy number 6–13 (broad region; genes not listed).
- chr8:5,363,371–6,257,537, 11 genes, copy number 5: AC007718.1, AC091193.1, RPL23AP54, AC004944.1, AC084768.1, AC084768.2, AC087369.1, AC087369.2, RN7SKP159, AC079054.1, AC009435.1.
- chr8:40,900,016–43,131,180, 59 genes, copy number 6: AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1.
- chr8:49,352,630–51,810,681, 17 genes, copy number 8: RFPL4AP7, AC090155.2, AC090155.1, PSAT1P1, AC113145.1, AC023762.1, SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1.
- chr8:72,462,311–74,321,540, 45 genes, copy number 5: AC011131.1, KCNB2, HAUS1P3, AC013562.2, AC013562.1, AC090735.1, AC022893.2, TERF1, RNU6-285P, AC022893.3, AC022893.1, SBSPON, AC100823.1, AC100823.2, C8orf89, PRXL2AP2, RPL7, RDH10, RDH10-AS1, AC111149.1, AC111149.2, STAU2-AS1, STAU2, AC018620.1, AC100784.1, VENTXP6, AC027018.1, AC022826.2, UBE2W, AC022826.1, RN7SL760P, AC022868.1, GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1, JPH1.
- chr8:74,347,757–74,376,793, 2 genes, copy number 5: AC103952.1, Y_RNA.
- chr8:79,259,402–145,066,685, 1,050 genes, copy number 5 (broad region; genes not listed).
- chr10:42,149,310–43,981,102, 64 genes, copy number 5 (broad region; genes not listed).
- chr10:46,375,752–52,298,423, 123 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr10:55,247,755–69,209,099, 152 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr10:72,467,749–75,431,588, 111 genes, copy number 5 (broad region; genes not listed).
- chr10:75,450,081–75,743,755, 5 genes, copy number 5: AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1.
- chr10:79,937,467–92,710,608, 237 genes, copy number 5 (broad region; genes not listed).
- chr11:747,415–2,270,952, 83 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr11:61,897,301–64,572,875, 157 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr11:66,257,294–67,683,058, 99 genes, copy number 6 (broad region; genes not listed).
- chr12:32,679,200–32,993,754, 14 genes, copy number 5: DNM1L, AC084824.2, Y_RNA, AC084824.5, AC084824.1, YARS2, AC084824.3, AC084824.4, AC087588.2, PKP2, AC087588.1, RPL35AP27, ASS1P14, AC087311.1.
- chr12:33,923,374–50,283,546, 303 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr12:54,830,518–64,990,646, 306 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr12:66,116,555–67,069,162, 14 genes, copy number 8 (within-gene range 3–8): LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4.
- chr12:68,143,318–70,354,993, 58 genes, copy number 6: AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1.
- chr12:71,007,773–74,545,430, 42 genes, copy number 6–9: AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1, AC090503.2, LINC02444, AC090503.1, AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1.
- chr12:75,391,089–77,065,569, 38 genes, copy number 6: GLIPR1L2, GLIPR1, AC121761.1, KRR1, AC078923.1, AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1, AC011611.6, RN7SL734P, AC011611.2, AC011611.1, PHLDA1, AC011611.3, AC011611.4, NAP1L1, AC011611.5, AC233290.2, AC233290.1, RNU6-1271P, LNCOG, RN7SKP172, BBS10, OSBPL8, AC107032.2, AC107032.3, RPL7AP9, YWHAQP7, AC107032.1, RPL7P43, AC093014.1, ZDHHC17, CSRP2, AC124784.1, AC025161.1, E2F7.
- chr13:26,222,191–29,505,947, 64 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr13:31,134,973–32,428,311, 17 genes, copy number 5 (within-gene range 4–5): HSPH1, B3GLCT, ANKRD26P4, AL161616.2, AL161616.1, RXFP2, AL138708.1, FRY, EEF1DP3, AC002525.1, Metazoa_SRP, FRY-AS1, ZAR1L, BRCA2, IFIT1P1, N4BP2L1, AL137247.1.
- chr13:33,285,866–33,349,619, 4 genes, copy number 7: AL627232.1, LINC02344, AL138999.2, AL138999.1.
- chr13:38,687,077–40,611,127, 23 genes, copy number 6–10 (within-gene range 4–10): FREM2, RNU6-56P, FREM2-AS1, PLA2G12AP2, ANKRD26P2, STOML3, PROSER1, NHLRC3, AL354809.1, NXT1P1, LHFPL6, COG6, MIR4305, RNY4P14, CDKN2AIPNLP3, AZU1P1, SNORD116, LINC00598, LINC00332, RPL17P51, RNY3P9, RN7SKP2, AL133318.1.
- chr13:41,061,509–41,506,248, 19 genes, copy number 10 (within-gene range 4–10): WBP4, MIR3168, RN7SL597P, KBTBD6, AL354696.2, CALM2P3, KBTBD7, MORF4L1P4, MTRF1, AL354696.1, RAC1P3, NAA16, RNU6-57P, TUBBP2, OR7E36P, OR7E155P, OR7E37P, RGCC, AL354833.2.
- chr13:98,142,562–99,088,625, 21 genes, copy number 5: FARP1, RNF113B, RN7SKP8, MIR3170, AL445223.1, AL161896.1, FARP1-AS1, STK24, AL356423.1, STK24-AS1, NUS1P4, CYCSP35, CALM2P4, RN7SL60P, SLC15A1, DOCK9, DOCK9-AS1, AL161420.1, RPL7L1P12, RNU6-83P, DOCK9-DT.
- chr14:18,333,726–106,875,071, 2,285 genes, copy number 5–7 (broad region; genes not listed).
- chr18:962,592–31,685,836, 508 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr20:87,250–53,668,758, 1,182 genes, copy number 6 (broad region; genes not listed).
- chr20:54,068,408–54,651,169, 6 genes, copy number 7 (within-gene range 3–7): MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5.

Autosomal genes at a single copy (total copy number 1): 2,523. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
